CPTAC case C3L-06639 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f474deeb-7246-42a4-87e8-4ad072c91de0

Demographics
Sex at birth: male; Race: white; Year of birth: 1950; Vital status: Alive; Country of birth: Russia.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Body of stomach; Age at diagnosis: 69.0 years (25,207 days); Year of diagnosis: 2019; AJCC staging edition: 8th; AJCC pathologic T: T4a; AJCC pathologic N: N3a; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Residual disease: R1; Days to last known disease status: 40 days; Days to last follow up: 40 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 7.7 cm; Lymph node involvement: Positive; Lymph nodes positive: 13; Lymph nodes tested: 27.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 40.

Exposures
- Tobacco smoking status: Current Smoker; Pack years smoked: 30.8; Cigarettes per day: 15; Tobacco smoking onset year: 1978; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-06639-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 40 days; Initial weight: 697 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-06639-21: Section location: Body; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3L-06639-05: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 40 days; Initial weight: 694 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-06639-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 40 days; Method of sample procurement: Blood Draw.
